MMRF case MMRF_1774 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2c2fda4e-7cb5-4417-b5fe-530fa1c5b42a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.5 years (23,925 days); ISS stage: I; Days to last known disease status: 1,083 days (3.0 years); Days to last follow up: 1,083 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 211 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 212 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 214 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 213 days; Days to treatment end: 305 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 306 days; Days to treatment end: 954 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 986 days (2.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,013 days (2.8 years); Days to treatment end: 1,013 days (2.8 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,015 days (2.8 years); Days to treatment end: 1,015 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 168 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 1.77 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 43.8 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 69 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 5.46 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.71 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 346 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.34 mmol/L.
- Day 166 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.98 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 4.73 mmol/L.
- Day 250: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 362 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 9.41 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 1.01 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 7.4 g/dL; Glucose 6.93 mmol/L.
- Day 446: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 9.98 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.95 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 531 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 615 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 6.33 mmol/L.
- Day 699 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.72 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 783: Serum Free Immunoglobulin Light Chain, Kappa 5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.44 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.03 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 867 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 9.77 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 6.77 mmol/L.
- Day 979 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 29.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 1,083 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 3.14 mmol/L.

Other clinical attributes
- Day -8: Weight: 108 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1774_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1774_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
